Somatic mutation profile of tumor specimen MMRF_1824_1_BM_CD138pos (aliquot MMRF_1824_1_BM_CD138pos_T1_KBS5U_L07233) from MMRF case MMRF_1824, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.0 years (25,202 days).
Specimen MMRF_1824_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e00f24b8-fe59-4d02-b64b-db19ddf1c09e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1824_2_PB_Whole (Blood Derived Normal), aliquot MMRF_1824_2_PB_Whole_C1_KBS5U_L07234; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eea6ecdb-a706-450a-a2db-cf7f6ae5ad88

The open-access MAF lists 128 somatic variants for this specimen: 45 protein-altering or splice-affecting, 15 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 44, Missense Mutation 39, Intron 15, Silent 15, 3'Flank 4, 5'Flank 3, Nonsense Mutation 2, 5'UTR 2, In Frame Del 1, Splice Region 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- CARS1 | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1318264763; called by muse, mutect2, varscan2
- CMAS | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); catalogued as rs1156625340; called by muse, mutect2
- FPR1 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1227141101, COSV59053817; called by muse, mutect2, varscan2
- FUT11 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.826); catalogued as rs776213343; called by muse, mutect2, varscan2
- FYCO1 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 53/198 reads (27%) | catalogued as rs774459862; called by muse, mutect2, varscan2
- GPR37 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.37); catalogued as rs369674783; called by muse, mutect2, varscan2
- HBS1L | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.115); catalogued as COSV63202844; called by muse, mutect2
- HCK | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV52941529; called by muse, varscan2
- IGHV2-70 | c.67T>G p.L23V | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs558615932; called by muse, varscan2
- MAGEF1 | c.818A>G p.Y273C | Missense Mutation (SNP) | VAF 64/231 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748459494; called by muse, mutect2, varscan2
- MAP10 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as COSV101406522; called by muse, mutect2
- MVP | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs137950833; called by muse, mutect2, varscan2
- MYLIP | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.635); catalogued as rs750549300; called by muse, mutect2, varscan2
- P2RX6 | c.973G>A p.V325I | Missense Mutation (SNP) | VAF 41/172 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.3); catalogued as rs533943590; called by muse, mutect2, varscan2
- PGBD2 | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs138323244; called by muse, mutect2, varscan2
- POMP | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.13); catalogued as COSV66481256; called by muse, mutect2, varscan2
- PTEN | c.1021T>G p.F341V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554825652, COSV64288696, COSV64295085; ClinVar: uncertain significance; called by muse, mutect2
- RYR1 | c.9373G>A p.V3125M | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.705); catalogued as rs1453799659; called by muse, mutect2, varscan2
- ABCC2 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- ADCY2 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AIMP1 | c.867A>T p.K289N | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- ANKLE1 | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- AP3B1 | c.1575_1589del p.T526_D530del | In Frame Del (DEL) | VAF 43/267 reads (16%) | called by mutect2, pindel, varscan2
- CALR | c.92-1G>C p.X31_splice | Splice Site (SNP) | VAF 14/68 reads (21%) | called by mutect2, varscan2
- CYP21A2 | c.950G>A p.R317Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- E2F8 | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 141/445 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- EPHA7 | c.1323A>T p.A441= | Splice Region (SNP) | VAF 59/159 reads (37%) | called by muse, mutect2, varscan2
- FNDC1 | c.2660C>T p.A887V | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- HMCN2 | c.14624A>G p.H4875R | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGHV2-70D | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- IGHV3-53 | c.296T>G p.L99R | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- KCNK12 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRRC75A | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2
- NUP214 | c.5848G>A p.G1950R | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51F1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- PARVG | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 41/165 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- PTPN13 | c.3665G>A p.R1222H (on ENST00000411767 / NM_080683.3; = p.R1203H on NM_006264.3) | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATS2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNNI3K | c.2144T>A p.V715D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ZCCHC2 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 4/67 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.411); called by muse, mutect2
- ZFP30 | c.490G>T p.G164W | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMAT3 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- ZNF596 | c.722del p.H241Lfs*31 | Frame Shift Del (DEL) | VAF 52/194 reads (27%) | called by mutect2, pindel, varscan2
- ZNF880 | c.545A>C p.K182T | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- AKAP9 | c.3255A>G p.R1085= | Silent (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- ATG13 | c.1377T>A p.L459= (on ENST00000359513 / NM_001346321.1; = p.L422= on NM_014741.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 54/169 reads (32%) | called by muse, mutect2, varscan2
- CFAP46 | c.4557G>A p.A1519= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as rs1206824389; called by muse, mutect2, varscan2
- DOCK11 | c.903G>A p.E301= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- DSN1 | c.852C>G p.V284= | Silent (SNP) | VAF 18/84 reads (21%) | called by muse, mutect2, varscan2
- FER1L6 | c.1782G>A p.L594= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs1242032306; called by muse, mutect2
- HCK | c.150G>A p.V50= | Silent (SNP) | VAF 66/290 reads (23%) | catalogued as rs1342560826, COSV99393860; called by muse, varscan2
- IGLC7 | c.222G>T p.L74= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- LRP1 | c.1701C>T p.H567= | Silent (SNP) | VAF 63/228 reads (28%) | catalogued as rs41291997, COSV54505432; called by muse, mutect2, varscan2
- MS4A12 | c.108A>T p.S36= | Silent (SNP) | VAF 128/398 reads (32%) | called by muse, mutect2, varscan2
- MYH14 | c.978C>T p.H326= | Silent (SNP) | VAF 20/225 reads (9%) | called by muse, mutect2
- NOTCH1 | c.4221C>T p.S1407= | Silent (SNP) | VAF 60/270 reads (22%) | catalogued as rs752575476; called by muse, mutect2, varscan2
- PKD1 | c.12657C>T p.F4219= (on ENST00000262304 / NM_001009944.3; = p.F4218= on NM_000296.4) | Silent (SNP) | VAF 43/121 reads (36%) | catalogued as rs752787455, COSV51911125; called by muse, mutect2, varscan2
- TST | c.204G>A p.A68= | Silent (SNP) | VAF 26/84 reads (31%) | called by muse, mutect2, varscan2
- ZNF106 | c.1281G>A p.E427= | Silent (SNP) | VAF 86/561 reads (15%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.2653+40A>G | Intron (SNP) | VAF 68/250 reads (27%) | called by muse, mutect2, varscan2
- AMER1 | c.*2643T>G | 3'UTR (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- CDH19 | c.*1362G>C | 3'UTR (SNP) | VAF 39/122 reads (32%) | called by muse, mutect2, varscan2
- CRACDL | c.-10-22286G>A | Intron (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- CRIM1 | c.2429-5356T>C | Intron (SNP) | VAF 55/235 reads (23%) | called by muse, mutect2, varscan2
- CRNKL1 | c.*1601C>T | 3'UTR (SNP) | VAF 27/120 reads (23%) | called by muse, mutect2, varscan2
- DCHS2 | n.2653-786dup | Intron (INS) | VAF 15/73 reads (21%) | catalogued as rs869095745; called by mutect2, pindel, varscan2
- DNAJC5 | c.493+151G>A | Intron (SNP) | VAF 5/85 reads (6%) | called by muse, mutect2
- DNAJC5 | c.*2631C>T | 3'UTR (SNP) | VAF 6/127 reads (5%) | called by muse, mutect2
- DUSP6 | c.*892dup | 3'UTR (INS) | VAF 32/151 reads (21%) | catalogued as rs1195446534; called by mutect2, varscan2
- EIF2B4 | c.31+168C>G | Intron (SNP) | VAF 28/102 reads (27%) | catalogued as COSV99277316; called by muse, mutect2, varscan2
- EMP2 | c.*703del | 3'UTR (DEL) | VAF 13/104 reads (13%) | catalogued as rs1257641178; called by mutect2, pindel, varscan2
- ENPP3 | c.-20T>C | 5'UTR (SNP) | VAF 14/484 reads (3%) | called by muse, mutect2
- EPB41L1 | c.*3051G>C | 3'UTR (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- FAM107A | c.*2139A>G | 3'UTR (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- FAM111A | c.81+101A>G | Intron (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- FAM53B | c.*2217T>A | 3'UTR (SNP) | VAF 43/160 reads (27%) | called by muse, mutect2, varscan2
- FCGR2B | c.*508T>A | 3'UTR (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- GABRG1 | c.*1576G>T | 3'UTR (SNP) | VAF 39/148 reads (26%) | called by muse, mutect2, varscan2
- GASK1B | c.*1817A>T | 3'UTR (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- GNAI1 | c.*1110T>A | 3'UTR (SNP) | VAF 15/45 reads (33%) | called by muse, mutect2, varscan2
- GPATCH1 | c.1893-21G>A | Intron (SNP) | VAF 37/175 reads (21%) | called by muse, mutect2, varscan2
- GPRIN2 | c.*7G>C | 3'UTR (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- GTDC1 | c.*196C>A | 3'UTR (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- IRX5 | c.*17C>G | 3'UTR (SNP) | VAF 93/318 reads (29%) | called by muse, mutect2, varscan2
- ITGA6 | chr2:172504320 G>A | 3'Flank (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2, varscan2
- KLHL6 | c.*2946_*2949del | 3'UTR (DEL) | VAF 43/163 reads (26%) | called by mutect2, pindel, varscan2
- LARP1B | c.988+1114G>A | Intron (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- LUC7L2 | c.*584G>A | 3'UTR (SNP) | VAF 25/101 reads (25%) | called by muse, mutect2, varscan2
- MAGEA11 | c.*200C>T | 3'UTR (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- MAP3K20 | c.987+5837G>A | Intron (SNP) | VAF 28/108 reads (26%) | catalogued as rs919616360; called by muse, mutect2, varscan2
- MBOAT2 | c.*1045C>G | 3'UTR (SNP) | VAF 51/181 reads (28%) | called by muse, mutect2, varscan2
- MSH6 | chr2:47807048 C>T | 3'Flank (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- NAV3 | c.*280A>G | 3'UTR (SNP) | VAF 5/101 reads (5%) | called by muse, mutect2
- NDUFA12 | c.170-36A>C | Intron (SNP) | VAF 42/160 reads (26%) | catalogued as rs750206302; called by mutect2, varscan2
- NDUFB6 | c.*689A>C | 3'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- NEGR1 | c.*1182T>C | 3'UTR (SNP) | VAF 24/82 reads (29%) | called by muse, mutect2, varscan2
- NEXN | c.*293_*296del | 3'UTR (DEL) | VAF 29/127 reads (23%) | called by mutect2, pindel, varscan2
- PCDH9 | c.3036+366C>A | Intron (SNP) | VAF 29/125 reads (23%) | called by muse, mutect2, varscan2
- PDLIM5 | c.*1808G>A | 3'UTR (SNP) | VAF 50/172 reads (29%) | called by muse, mutect2, varscan2
- PDPN | c.67+27G>A | Intron (SNP) | VAF 38/146 reads (26%) | catalogued as rs781163541; called by muse, mutect2, varscan2
- PFKFB4 | c.*206G>A | 3'UTR (SNP) | VAF 33/120 reads (28%) | called by muse, mutect2, varscan2
- PID1 | chr2:229024453 G>A | 3'Flank (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- PIM2 | c.*718G>A | 3'UTR (SNP) | VAF 18/76 reads (24%) | called by muse, mutect2, varscan2
- PRKAB2 | c.*3514G>A | 3'UTR (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- PRLHR | c.*684G>A | 3'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- PTAR1 | c.*5711A>G | 3'UTR (SNP) | VAF 77/163 reads (47%) | called by muse, mutect2, varscan2
- PUS1 | c.545-15C>T | Intron (SNP) | VAF 28/127 reads (22%) | catalogued as rs1476682983; called by muse, mutect2, varscan2
- RAP1GDS1 | c.*220C>T | 3'UTR (SNP) | VAF 32/97 reads (33%) | called by muse, mutect2, varscan2
- RBL1 | c.*2378A>G | 3'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- RHOBTB2 | chr8:22994592 C>A | 5'Flank (SNP) | VAF 58/170 reads (34%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22601483 G>T | 5'Flank (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- SATB2 | c.*501C>G | 3'UTR (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- SEMA3E | c.*897A>G | 3'UTR (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- SIKE1 | c.*1742A>G | 3'UTR (SNP) | VAF 36/117 reads (31%) | called by muse, mutect2, varscan2
- SLC35F3 | c.283+35G>T | Intron (SNP) | VAF 268/414 reads (65%) | called by muse, mutect2, varscan2
- SMPD3 | c.*50C>T | 3'UTR (SNP) | VAF 22/65 reads (34%) | catalogued as rs750082736; called by muse, mutect2, varscan2
- SPATA18 | c.*1661del | 3'UTR (DEL) | VAF 31/111 reads (28%) | catalogued as rs967623198; called by mutect2, pindel, varscan2
- SPHK2 | c.-143C>T | 5'UTR (SNP) | VAF 21/168 reads (13%) | catalogued as rs893518861; called by muse, mutect2, varscan2
- SRGAP3 | c.*3231del | 3'UTR (DEL) | VAF 30/112 reads (27%) | catalogued as rs200351418; called by mutect2, varscan2
- SRSF12 | c.*2322G>C | 3'UTR (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- TBX18 | c.*63del | 3'UTR (DEL) | VAF 8/41 reads (20%) | catalogued as rs762216531; called by mutect2, pindel, varscan2
- TRPS1 | chr8:115411225 T>A | 3'Flank (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- TSEN34 | c.*43C>T | 3'UTR (SNP) | VAF 36/184 reads (20%) | catalogued as rs771901856; called by muse, mutect2, varscan2
- TSPAN9 | c.*604C>A | 3'UTR (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- USP46 | c.*3138T>C | 3'UTR (SNP) | VAF 35/149 reads (23%) | called by muse, mutect2, varscan2
- ZNF37A | c.*2389del | 3'UTR (DEL) | VAF 38/136 reads (28%) | called by mutect2, varscan2
- ZNF606 | chr19:58007677 A>G | 5'Flank (SNP) | VAF 32/146 reads (22%) | called by muse, mutect2, varscan2
